CCDI case PBBVLI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/e98c3ba2-d5e1-453f-8133-abac61575486

Demographics
Sex at birth: male.

Diagnoses (1)
1. Sarcoma, NOS: ICD-O-3 morphology code: 8800/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 0.0 years (8 days).

Biospecimens (3 samples)
- Sample 0DIMVP: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DIMWK: Tissue type: Normal; Specimen type: Peripheral Whole Blood. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample 0DIMX1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
